MMRF case MMRF_2159 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/21a2751c-648d-4526-9b55-099cc1853788

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.3 years (21,649 days); ISS stage: I; Days to last known disease status: 904 days (2.5 years); Days to last follow up: 904 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 90 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 72 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 91 days; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 91 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 45.4 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 9 g/dL; Glucose 6.11 mmol/L; C-Reactive Protein 0.033 mg/dL.
- Day 91 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 36.5 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.53 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 8.3 g/dL; Glucose 5.06 mmol/L.
- Day 176 (ECOG 1): M Protein 0.05 g/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6.3 g/dL; Glucose 4.68 mmol/L.
- Day 261: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 31.7 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 7.4 g/dL; Glucose 4.68 mmol/L.
- Day 379: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 31.3 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.3 g/dL; Glucose 4.84 mmol/L.
- Day 455 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 34.4 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 7.9 g/dL; Glucose 4.79 mmol/L.
- Day 540 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 22.8 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 4.95 mmol/L.
- Day 638 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 35 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 8.4 g/dL; Glucose 4.68 mmol/L.
- Day 715 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 38.9 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 8.7 g/dL; Glucose 4.9 mmol/L.
- Day 807 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 31.5 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 7.8 g/dL; Glucose 4.62 mmol/L.
- Day 904 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 26 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 8.4 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day -5: Weight: 91 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2159_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2159_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
